Gene-level copy-number profile of tumor specimen TCGA-25-2409-01A from TCGA case TCGA-25-2409, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-25-2409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e7acdc39-9016-45df-bb67-56626afa7fe3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2409-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97bd38f3-11f8-4780-a834-d01f07d6d47c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 2; copy number 2: 10,432; copy number 3: 9,394; copy number 4: 31,557; copy number 5: 3,400; copy number 6: 3,594; copy number 7: 18; copy number 8: 722; copy number 9: 251; copy number 10: 387; copy number 22: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-2409-01): tumor purity 0.72, ploidy 3.79, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,165,552, 48 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr18:74,211,391–74,240,555, 2 genes (within-gene range 0–2): AC090398.1, RN7SL551P.
- chr19:57,664,280–57,717,301, 3 genes (within-gene range 0–2): TPRG1LP1, ZSCAN4, ZNF551.
- chr19:57,697,367–57,709,194, 1 gene (within-gene range 0–2): ZNF154.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 644 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–990,053, 24 genes, copy number 9 (within-gene range 5–9): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52.
- chr12:1,380,060–7,936,187, 227 genes, copy number 9 (broad region; genes not listed).
- chr12:39,170,646–39,619,803, 6 genes, copy number 22 (within-gene range 2–22): AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2.
- chr19:7,348,943–14,007,039, 387 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
